Gene-level copy-number profile of tumor specimen HCM-CSHL-0664-C18-06A from HCMI case HCM-CSHL-0664-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 61.4 years (22,442 days).
Specimen HCM-CSHL-0664-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 74f6d0b6-7991-4a36-8b21-efe51e0c990d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0664-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/6ddbbb7c-3a3b-4051-87d4-ba11453183c0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 1,157; copy number 2: 6,828; copy number 3: 21,639; copy number 4: 22,867; copy number 5: 644; copy number 6: 2,071; copy number 7: 23; copy number 8: 1,303; copy number 9: 3; copy number 10: 1,180; copy number 11: 1,184.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:32,549,940–32,560,022, 2 genes (within-gene range 0–1): RNU1-61P, HLA-DRB6.
- chr18:5,392,381–5,630,700, 3 genes: EPB41L3, AP005059.2, AP005059.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,367 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:38,901,235–38,988,663, 3 genes, copy number 9: PLEKHA2, AC108863.1, HTRA4.
- chr8:46,028,804–145,066,685, 1,494 genes, copy number 10–11 (broad region; genes not listed).
- chr20:30,214,765–64,327,972, 870 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 645. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
